Somatic mutation profile of tumor specimen TCGA-06-2559-01A (aliquot TCGA-06-2559-01A-01D-1494-08) from TCGA case TCGA-06-2559, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.7 years (30,580 days).
Specimen TCGA-06-2559-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05f43051-2927-4c29-8070-3a0ec9e47213.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2559-10A (Blood Derived Normal), aliquot TCGA-06-2559-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fb5d2c0-4c3b-4f6b-ace9-6fb918623a8e

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 37, Silent 19, Splice Region 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519724, COSV64288957, COSV64298985; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BCOR | c.3653G>A p.W1218* (on ENST00000378444 / NM_001123385.2; = p.W1184* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 80/90 reads (89%) | catalogued as COSV60705485; called by muse, mutect2, varscan2
- CASKIN2 | c.3093_3095del p.P1032del | In Frame Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs950461956; called by pindel, varscan2
- CHD8 | c.2671G>C p.G891R (on ENST00000646647 / NM_001170629.2; = p.G612R on NM_020920.4) | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67872338; called by muse, mutect2, varscan2
- COL17A1 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 114/138 reads (83%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs763518143, COSV62227033, COSV62229351; called by muse, mutect2, varscan2
- GRM8 | c.2030T>C p.F677S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58860088; called by muse, mutect2, varscan2
- IL18RAP | c.796+1G>T p.X266_splice | Splice Site (SNP) | VAF 43/82 reads (52%) | catalogued as COSV51824366, COSV51828651; called by muse, mutect2, varscan2
- KCTD19 | c.2302G>A p.V768M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as rs773175029, COSV58574635; called by muse, mutect2, varscan2
- KIR2DL4 | c.232G>A p.A78T (on ENST00000396284; = p.A39T on NM_001080770.2) | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs369994438, COSV60877402; called by muse, mutect2, varscan2
- KRCC1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 20/561 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV61252138; called by muse, mutect2
- LRP2 | c.12389T>C p.L4130P | Missense Mutation (SNP) | VAF 198/415 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55569927; called by muse, mutect2, varscan2
- LRRC40 | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63943178; called by muse, mutect2, varscan2
- LTBP1 | c.1032G>A p.Q344= | Splice Region (SNP) | VAF 68/164 reads (41%) | catalogued as COSV63196148; called by muse, mutect2, varscan2
- MAP3K1 | c.1462T>C p.C488R | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68126715; called by muse, mutect2, varscan2
- MAPK1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53185206, COSV53188915; called by muse, mutect2, varscan2
- MOCS1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); catalogued as rs1314629193, COSV57940023; called by muse, mutect2, varscan2
- NEUROG2 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57637951; called by muse, mutect2, varscan2
- NEXN | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV53944319; called by muse, mutect2, varscan2
- NLRC5 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 20/578 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs952638793, COSV52652607; called by muse, mutect2
- NLRP4 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs756196545, COSV56712737, COSV56721500; called by muse, mutect2, varscan2
- NPAP1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755681616, COSV100274534, COSV61510472; called by muse, mutect2, varscan2
- ODF4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs147153349, COSV60272108; called by muse, mutect2, varscan2
- OR10S1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771347462, COSV73342706; called by muse, mutect2, varscan2
- OR7A17 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs964223126, COSV59414366; called by muse, mutect2
- PCDH11X | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as rs772498943, COSV53497403; called by muse, mutect2, varscan2
- PDGFRA | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 415/1737 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV57272637; called by muse, mutect2, varscan2
- PDGFRA | c.1965G>C p.L655F | Missense Mutation (SNP) | VAF 213/1589 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57272642, COSV99957332; called by muse, mutect2, varscan2
- PRDM9 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.235); catalogued as COSV57011927; called by muse, mutect2, varscan2
- PSG5 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV61654835; called by muse, mutect2, varscan2
- PTPRS | c.3359A>G p.N1120S | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs372506721, COSV53634249; called by muse, mutect2, varscan2
- RGS12 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs200575024, COSV58749223; called by muse, mutect2, varscan2
- SCNN1G | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55597975, COSV55601439; called by muse, mutect2, varscan2
- SMG8 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 136/285 reads (48%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); catalogued as COSV56286740; called by muse, mutect2, varscan2
- SPTA1 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV63758056; called by muse, mutect2, varscan2
- TAF1L | c.4999G>A p.D1667N | Missense Mutation (SNP) | VAF 163/407 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV54267636; called by muse, mutect2, varscan2
- TAF6 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV59843257; called by muse, mutect2, varscan2
- TMF1 | c.2765A>G p.K922R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV68375617; called by muse, mutect2
- TMPPE | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56567324; called by muse, mutect2, varscan2
- TG | c.7065del p.L2356Cfs*8 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by pindel, varscan2
- ZNF658 | c.2874A>T p.R958S | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADAMTS14 | c.1467C>T p.G489= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV64605633; called by muse, mutect2, varscan2
- ADGRV1 | c.7153C>T p.L2385= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV67993636; called by muse, mutect2, varscan2
- ANKRD30A | c.3171G>A p.E1057= (on ENST00000611781; = p.E1001= on NM_052997.2) | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV64618769; called by muse, mutect2, varscan2
- CAPN15 | c.3204C>T p.T1068= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV54834544; called by muse, mutect2
- CPN2 | c.753C>T p.N251= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs753849442, COSV60469685; called by mutect2, varscan2
- DHRS2 | c.339C>T p.G113= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs1393894434, COSV51631007; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.102C>T p.G34= | Silent (SNP) | VAF 47/200 reads (24%) | catalogued as rs558722857, COSV66964467; called by muse, mutect2, varscan2
- FBN2 | c.1452C>A p.I484= | Silent (SNP) | VAF 88/217 reads (41%) | catalogued as COSV52539762, COSV99330231; called by muse, mutect2, varscan2
- HRNR | c.1269T>C p.S423= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV64262019; called by muse, mutect2
- IL2RB | c.1296C>A p.P432= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs143704470; called by muse, mutect2, varscan2
- ITGAD | c.387G>A p.S129= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs750617929, COSV66757365; called by muse, mutect2, varscan2
- KRT27 | c.708G>A p.A236= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV56971978, COSV56973101; called by muse, mutect2, varscan2
- LRP2 | c.3213G>A p.A1071= | Silent (SNP) | VAF 21/221 reads (10%) | catalogued as rs530329919, COSV55569939; called by muse, mutect2
- MYH13 | c.4671C>T p.H1557= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs764908477, COSV52840110; called by muse, mutect2, varscan2
- OTOA | c.483C>T p.L161= | Silent (SNP) | VAF 95/227 reads (42%) | catalogued as rs756856872, COSV53762469; called by muse, mutect2, varscan2
- PCDHGB4 | c.1518C>T p.S506= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV54014637; called by muse, mutect2, varscan2
- SEPTIN4 | c.729G>T p.L243= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV57898977; called by muse, mutect2, varscan2
- TAF1 | c.5295C>T p.D1765= (on ENST00000373790 / NM_138923.4; = p.D1786= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs769031881, COSV52122881; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3132G>A p.V1044= | Silent (SNP) | VAF 82/213 reads (38%) | catalogued as COSV51956593, COSV51959480; called by muse, mutect2, varscan2
